Surgical pathology report (de-identified scan), TCGA case TCGA-55-7576, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7576-01A (Primary Tumor).

[page 1 of 4]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession:
Physician:

PROCEDURE

Right thoracotomy.

SPECIMEN:

A. Right upper lobe FS. B. R4 lymph node. C. Subcarinal lymph node.

HISTORY

Right upper lobe nodules (x2).

GROSS

A. "Right upper lobe freeze bronchial margins." Received fresh for immediate evaluation and frozen section analysis is a partly collapsed lobe of lung, which has a small amount of hemorrhage over the surface. Most of the pleural surfaces are smooth, glistening and light to medium purple-brown. It weighs 240 grams. The bronchial resection margin portion of the most hilar aspect of the specimen is a bronchus 1.1 x 0.9 cm across. This resection margin is shaved from the specimen and submitted as a frozen section block. Two nodules are palpated in the upper aspect of the lobe and both show some degree of overlying puckering of the pleural surfaces. These are marked by me with blue dye. The more lateral lesion is cut across and reveals a subpleural, white and gray speckled lesion 2.0 x 1.7 cm on cut surface. A portion of this is removed for the tumor genome project in the usual manner. The second nodule, which is more apically situated, has its epicenter about 2 cm away from the lesion mentioned above and has more of a yellowish cut surface, is well circumscribed and up to 1.8 x 1.7 cm and presents focally just beneath the pleural surface, also with some overlying puckering of pleura. A portion of this tumor is also sampled for the tumor genome project.

After preparation of the frozen section, the frozen section remnant is placed in a block and the remainder of the tissue is fixed prior to further processing.

After fixation of the specimen, the frozen section control is processed as block FSA1. Additional tissues in the region of the vascular and bronchial margins are taken after removing staples, in block A2, which include apparent vascular margins, additional

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
Surg Path Final Report

* Final Report *

bronchial tissue and parabrachial lymph nodes. The more lateral tumor site is then sampled as multiple pieces in blocks A3 and A4, including overlying puckered pleural surfaces.

A5. This is a vertical section taken between the two foci of tumors, which appears to be free of gross tumor. This section will let us know whether there is direct connection between the nodules or not, on a microscopic level.

A6-A7. More apical, second focus and overlying puckered pleural surface.

Upon further inspecting the specimen after fixation, the two foci of tumors appear to be fairly close together, perhaps as close as 5 mm, and may be continuous as a "dumbbell" fashion if connected. A section of uninvolved lung tissue from the lower aspect of the lobe is taken as block A8.

B. "R4 lymph node." A mostly dark black and focally yellow piece of tissue is 1.4 x 1.2 x up to 0.5 cm. It is bisected.

C. "Subcarinal lymph node." Three pieces of jet black tissue are from 4, 9 and 16 mm across. Only the largest is bisected but all material is then processed as one block.

FROZEN SECTION DIAGNOSIS

A. Bronchial resection margin negative for tumor.

MICROSCOPIC

A. The frozen section control confirms the frozen section findings of a proximal bronchial resection margin that is negative for tumor. The two foci containing gross tumor, the more laterally situated and the more atypically situated have identical histology with areas showing adenocarcinoma growing in scar tissue with some areas showing more clear cell patterns to the cytoplasm and other areas having more eosinophilic and darker cytoplasm. Some of the latter tumor grows in a lepidic pattern including focally into the visceral pleura, with at least one small focus deposited and stuck to the outside of the visceral pleura. Deeper sections have been made of these foci. The section taken between the two nodules, although not grossly involved, has microscopic involvement of additional invasive adenocarcinoma which therefore shows a connection between these two otherwise apparently separate nodules. Thus, I think this is a single tumor with a so-called dumbbell shape and both foci of tumors making the larger nodules have mixtures of clear-type cytoplasm and eosinophilic-type cytoplasm. Emphysema is also found within the lung.

A focus of tumor shows growth into a thick-walled blood vessel, probably a vein. A single parabrachial lymph node is found and is negative for metastatic disease.

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Surg Path Final Report

* Final Report *

B. The lymph node is studied at multiple cuts through the node and is enlarged and has reactive changes, but does not contain metastatic disease.

C. The lymph node is enlarged, has reactive changes and is negative for metastatic disease.

The case is seen by Dr. [REDACTED] who is in agreement with the following diagnoses.

DIAGNOSIS

A. Right upper lung lobe, biopsy with frozen section:
Invasive moderately differentiated adenocarcinoma.
CPT 88307, 88331

Parabronchial lymph node negative for metastatic disease.
CPT 88305

B. R4 lymph node, biopsy:
Reactive lymph node, negative for tumor.
CPT 88305

C. Subcarinal lymph node, biopsy:
Reactive lymph node negative for tumor. [REDACTED]
CPT 88305

SYNOPTIC REPORT - LUNG

SPECIMEN: Lung.
PROCEDURE: Lobectomy.
SPECIMEN INTEGRITY: Single, intact.
SPECIMEN LATERALITY: Right.
TUMOR SITE: Upper lobe.
TUMOR SIZE: Approximately 4.3 cm (dumbbell shaped, two nearby nodules connected microscopically).
TUMOR FOCALITY: Single focus but with two dominant nodules.
HISTOLOGIC TYPE: Adenocarcinoma.
HISTOLOGIC GRADE: 2.
VISCERAL PLEURA INVASION: Yes.
TUMOR EXTENSION: Tiny amount on outer surface of visceral pleura.
MARGINS: Neg.
Bronchial margin: Neg.
Vascular margin: Neg.
Parenchymal margin: Neg.
Parietal pleural margin: Not sampled.
Chest wall margin: Not sampled.
Other attached tissue margin: Not sampled.
Distance of invasive carcinoma from closest margin: About 5 cm.
TREATMENT EFFECT: None.
LYMPH-VASCULAR INVASION: Not identified.
LYMPH NODES: Negative, reactive.

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Surg Path Final Report

* Final Report *

OTHER FINDINGS: Emphysema.

PATHOLOGICAL TNM (AJCC 7th ed.):

TNM DESCRIPTORS:

pT: 2a PL2.

pN: 0.

(Electronic Signature)

Completed Action List:

* Order by

Type:

Date:

Status:

Title:

Encounter info:

Printed by:

Printed on:

Source: NCI Genomic Data Commons file 8b83153c-2d91-459e-8074-75593731bf69 (TCGA-55-7576.FEAC18C2-CE79-4092-AD5A-98143981A24E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).